Gene-level copy-number profile of tumor specimen TCGA-12-0776-01A from TCGA case TCGA-12-0776, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 52.6 years (19,228 days).
Specimen TCGA-12-0776-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.9cf0189f-9b44-49a9-9b77-17705518375d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-12-0776-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ae7cc02a-8292-40e6-9c28-9b0de1b9fe8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 14,959; copy number 2: 39,024; copy number 3: 5,378; copy number 4: 220; copy number 5: 42; copy number 6: 98; copy number 7: 10; copy number 8: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-12-0776-01): tumor purity 0.5, ploidy 1.87, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:31,753,867–32,113,029, 13 genes (within-gene range 0–1): DEPDC5, Z82190.2, RN7SL20P, AL022331.1, RNU6-201P, Z82190.1, C22orf24, YWHAH, AL008719.1, LINC02558, RN7SL305P, Z74021.1, SLC5A1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 223 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,721,724–55,433,742, 11 genes, copy number 6: AC011228.2, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr12:55,997,180–60,363,935, 158 genes, copy number 6–8 (broad region; genes not listed).
- chr14:24,299,850–24,419,283, 10 genes, copy number 7 (within-gene range 3–7): NOP9, CIDEB, LTB4R2, LTB4R, ADCY4, AL096870.1, RIPK3, U6, NFATC4, NYNRIN.
- chr14:25,647,304–26,143,305, 1 gene, copy number 8 (within-gene range 3–8): LINC02306.
- chr14:25,916,015–25,998,805, 1 gene, copy number 8: AL132633.1.
- chr14:29,576,479–31,026,401, 24 genes, copy number 5: PRKD1, AL356756.1, RNU6-1234P, AL355053.1, AL133372.3, AL133372.2, AL133372.1, AL079305.1, G2E3-AS1, AL117355.1, SYF2P1, G2E3, SCFD1, UBE2CP1, AL121852.1, RPL12P5, AL049830.2, AL049830.1, COCH, AL049830.3, STRN3, HIGD1AP17, MIR624, AL049830.4.
- chr14:36,647,083–38,041,442, 18 genes, copy number 5 (within-gene range 3–5): AL079303.1, PAX9, SLC25A21, AL162464.2, AL162464.1, MIR4503, AL079304.1, SLC25A21-AS1, RNU6-273P, MIPOL1, RNU6-886P, AL121790.2, AL121790.1, FOXA1, TTC6, AL136296.1, RNU6-1277P, LINC00517.

Autosomal genes at a single copy (total copy number 1): 12,572. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
